HCMI case HCM-CSHL-0434-C24 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c4025241-d423-4daa-b0fc-b27873d4e314

Demographics
Sex at birth: male; Year of birth: 1956.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C24; Tissue or organ of origin: Extrahepatic bile duct; Site of resection or biopsy: Extrahepatic bile duct; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,282 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Lymph nodes positive: 15; Lymph nodes tested: 75; Lymphatic invasion present: No; Necrosis present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -12 days.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C77; Tissue or organ of origin: Extrahepatic bile duct; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 61.0 years (22,282 days).

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 449, day 852.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80 kg; Height: 165 cm; BMI: 29.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0434-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-CSHL-0434-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0434-C24-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 45; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 9; Percent neutrophil infiltration: 9.
  Slide HCM-CSHL-0434-C24-06A-01-S1-HE: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 45; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 9; Percent monocyte infiltration: 12; Percent neutrophil infiltration: 9.
- Sample HCM-CSHL-0434-C24-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0434-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Sample HCM-CSHL-0434-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
